Surgical pathology report (de-identified scan), TCGA case TCGA-JL-A3YX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site ABS - Research Metrics Pakistan, specimen TCGA-JL-A3YX-01A (Primary Tumor).

CLINICAL INFORMATION/COMMENTS:

LAB NO :	C.P.# :	
FEMALE - YEARS	Loc :	PR
PATIENT CODE :		
CONSULTANT :		
DATE :	PRINTED ON	

Histopathology Biopsy Small

Clinical Note:

Carcinoma breast left side.

Microscopic Features:

Section examined reveal breast tissue an infiltrative neoplastic lesion composed of cells showing moderate pleomorphism with nuclear hyperchromasia and eosinophilic cytoplasm. Few mitotic figures are seen. Almost 100% of the tumor is viable. No areas of necrosis are seen.

Conclusion:

Carcinoma left breast :-

Infiltrating Lobular Carcinoma grade II. 100% of tumor is viable. No areas of necrosis are seen.

Additional Report

Necrosis : 0%.
Percent of tumor nuclei : 90%.
Other nuclei : 10%.

1CB-0-3
Carcinoma, infiltrating lobular, NOS
8520/3
Site: breast, NOS C50.9
lw
6/17/12

Source: NCI Genomic Data Commons file 698dcb29-dca9-4a96-a80c-a6f476d85cd6 (TCGA-JL-A3YX.25782EF0-8786-446E-ADBA-21F489844237.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).